Surgical pathology report (de-identified scan), TCGA case TCGA-UY-A78N, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UY-A78N-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3
Carcinoma, urothelial NOS
8/20/13
Site Bladder NOS
C67.9
JW 8/20/13

- SOURCE:
- A. Distal right ureter (FS)
- B. Distal left ureter (FS)
- C. Bladder urinary with prostate (FS)
- D. Left pelvic lymph node dissection
- E. Right pelvic lymph nodes
- F. Left ureter final margin
- G. Right ureter final margin

DIAGNOSIS:

- A. Ureter, right distal, biopsy: No tumor.
- B. Ureter, left distal, biopsy: No tumor.
- C. Urinary bladder/prostate, cystectomy/prostatectomy:
- 1. Bladder with invasive high-grade urothelial carcinoma; see comment.
- 2. Prostatic adenocarcinoma, Gleason grade 3+3; see comment.
- 3. No tumor in one lymph node (0/1).
- D. Lymph nodes, left pelvic, dissection: No tumor in seven lymph nodes (0/7).
- E. Lymph nodes, right pelvic, dissection: Metastatic urothelial carcinoma involving one of seven lymph nodes (1/7); see comment.
- F. Ureter, left final margin, biopsy: No tumor.
- G. Ureter, right final margin, biopsy: No tumor.

CLINICAL DATA:

The patient is an ~~60~~-year-old male with bladder cancer, who undergoes cystectomy and prostatectomy.

GROSS DESCRIPTION:

The specimen is received in seven parts, each labeled with the patient's name and medical record number. Parts A-E are received fresh. Parts F-G are received in formalin.

Part A, additionally labeled "distal right ureter," consists of a single pink, unoriented tissue fragment measuring 0.7 x 0.6 x 0.2 cm. The entire specimen is frozen for frozen section 1, with the remnant submitted in cassette A1.

Part B, additionally labeled "distal left ureter," consists of a single pink-red, unoriented, soft tissue fragment measuring 0.6 x 0.6 x 0.3 cm. The entire specimen is frozen for frozen section 2, with the remnant submitted in cassette B1.

Part C, additionally labeled "urinary bladder and prostate," consists of a 320 gm cystectomy/prostatectomy specimen measuring 11.8 cm from superior to inferior x 8.0 cm from medial to lateral x 6.5 cm from anterior to posterior. The prostate itself measures approximately 5.0 x 5.0 x 4.0 cm. The specimen is

[page 2 of 3]
inked black on the posterior surface, green on the right anterior surface and blue on the left anterior surface, and is opened along the anterior surface to reveal a firm mass just lateral to the right ureteral orifice. This mass measures approximately 4.0 x 3.5 x 2.2 cm and, on sectioning, reveals firm, tan-gray parenchyma. The mass grossly infiltrates into the surrounding fat and is approximately 0.6 cm from the inked surgical margin, grossly. The mass approaches the prostate to approximately 1.1 cm, grossly. The remaining bladder mucosa is tan-pink, with no focal lesions, and the ureters and urethra appear unremarkable. The prostate is sectioned to reveal tan-beige parenchyma with no clear focal lesions. The fat surrounding the bladder is carefully examined for lymph nodes. The distal urethral margin is removed and submitted for frozen section 3, with the frozen section remnant submitted in cassette C1.

Additional representative sections are submitted as follows: Cassette C2:

Additional fragments of apical prostate. Cassette C3: Right ureteral margin (green ink) and left ureteral margin (black ink). Cassettes C4-C6: Tumor with radial margin. Cassettes C7-C8: Tumor approaching prostate. Cassette C9: Additional section of tumor with radial margin. Cassette C10: Representative section of dome of bladder. Cassette C11: Representative sections of left bladder wall. Cassette C12: Right mid prostate. Cassette C13: Left mid prostate. Cassette C14: Right base of prostate. Cassette C15: Left base of prostate. Cassette C16: Right seminal vesicle. Cassette C17: Left seminal vesicle. Cassette C18: Candidate lymph nodes, superior to bladder. Cassette C19: Candidate lymph nodes, left side. Cassette C20: Candidate lymph nodes, right side.

Part D, additionally labeled "left pelvic lymph node dissection," consists of multiple fragments of fibroadipose tissue measuring 5.0 x 4.0 x 3.2 cm in aggregate. The specimen is examined for candidate lymph nodes, which are submitted in cassettes D1-D2.

Part E, additionally labeled "right pelvic lymph node," consists of multiple fragments of fibroadipose tissue measuring 6.0 x 4.5 x 2.3 cm in aggregate. A large candidate lymph node is bisected and entirely submitted in cassette E1. Remaining candidate lymph nodes are submitted in cassettes E2-E3.

Part F, additionally labeled "6 - left ureter final margin," consists of one soft, pink-tan, irregular, unoriented, cylindrical tissue fragment with one set of attached, white sutures and two white metal staples, that measures 1.7 cm in length and 0.5 cm in average diameter. Sutures and staples are removed. The specimen is cross-sectioned and entirely submitted in cassette F1.

Part G, additionally labeled "7 - right ureter final margin," consists of one soft, pink-tan, irregular, unoriented, cylindrical tissue fragment with one set of attached, black sutures, that measures 1.5 cm in length and 0.3 cm in average diameter. The sutures are removed. The specimen is cross-sectioned and entirely submitted in cassette G1.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the

. They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

COMMENTS:

Bladder Tumor Synoptic Comment 1. Tumor type: Urothelial carcinoma. 2. Tumor grade: High-grade. 3. Tumor size: 4.0 cm maximum diameter. 4. Extent of tumor in bladder: Invasion through muscularis propria into peri-vesicle tissue. 5. Lymphatic/vascular invasion: Lymphatic and blood vessel invasion identified. 6. Epithelial abnormalities in bladder: Focal giant cell reaction and acute/chronic inflammation with reactive atypia. There

[page 3 of 3]
is mild cytological atypia but insufficient for a diagnosis of low grade dysplasia. 7. Extension of tumor into organs adjacent to bladder: No adjacent organs involved. 8. Surgical margins: All margins free of tumor; see additional comment below. 9. Lymph nodes: One of fifteen lymph nodes contains metastatic tumor (1/15); the largest metastatic deposit measures 0.3 cm in greatest dimension; there is no extranodal tumor growth. 10. Other pathologic findings in bladder: None identified. 11. AJCC/UICC stage: pT3aN1MX. 12. Additional comments: The urothelial carcinoma extends to within 0.3 cm of the inked radial specimen margin, and extends to within 0.5 cm of the prostate.

A small focus of prostatic adenocarcinoma (Gleason 3+3) is identified in the left mid prostate (C13). No perineural invasion is identified, and the tumor extends to within 0.5 cm of the right lateral specimen margin. High molecular weight keratin stain and p63 immunohistochemical stains are performed and evaluated on block C13 to further evaluate the prostatic adenocarcinoma. Both stains highlight the lack of basal cells confirming the diagnosis. Level sections are performed and evaluated on blocks C7, C20 and D2 to reach the above diagnoses.

Source: NCI Genomic Data Commons file af1a02ee-c27d-45d4-b185-ae838e730371 (TCGA-UY-A78N.9DE74A4B-6785-40FE-8117-496F4A32DFE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).